Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2H, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2H-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

- A. Lymph nodes, common hepatic artery, biopsy: Negative for tumor.
B. Lymph node, mesenteric, biopsy: Negative for tumor.
C. Common hepatic duct, margin, excision: Negative for tumor.
D. Pancreatic neck, margin, excision: Negative for tumor.
E. Head of pancreas, duodenum, portion of jejunum and gallbladder, whipple resection: Invasive moderately to poorly differentiated cholangiocarcinoma is identified forming a solid mass (4.3 x 3.1 x 0.8 cm) located in the distal common bile duct. The tumor extends into pancreas. Perineural invasion is present. Angiolymphatic invasion is absent. All surgical resection margins (after re-excision of the uncinate margin, see specimen F) are negative for tumor (minimum tumor free margin, 1.0 cm, uncinate margin). Multiple (22) regional lymph nodes are negative for metastatic tumor. Gallbladder is negative for tumor.
F. Lymph nodes, new uncinate margin, excision: Multiple (3) lymph nodes are negative for tumor. New uncinate margin is negative for tumor.

ICD-C-B

Cholangiocarcinoma 8162x3
Site: Intrahepatic bile duct C22.1
JG 5/8/14

Source: NCI Genomic Data Commons file 983dec71-195c-4c49-93cb-955dd3ed6ac9 (TCGA-W5-AA2H.46A92484-5ECB-4F04-9207-4188D015B9CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).